Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8258, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8258-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Bilateral pelvic lymph node; excision:
No metastatic carcinoma identified in two lymph nodes (0/2).
- B. Prostate; radical prostatectomy:
- Tumor Characteristics:**
1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 4.5 x 4.0 x 3.0 cm, 24 grams.
3. Tumor quantitation: Tumor involves approximately 5% of prostate volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 6/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Adenocarcinoma is less than 0.1 cm from the right apical margin.
Bladder neck and inked prostatic margin negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes received: 2 pelvic nodes, see specimen A.
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/2).

Other:

1. pTNM stage: pT2c N0.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Bilateral pelvic lymph nodes
B. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers labeled with the patient's name

A. Additionally labeled #1 and contains a 5.8 x 3.5 x 1.9 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, two yellow-tan firm fatty nodules are identified consistent with possible lymph nodes. Each are 5.5 cm in greatest dimension. They are sectioned and entirely submitted in cassettes A1-4 labeled designated as follows: 1-2--one whole possible lymph node, quadrisectioned; 3-4--one whole possible lymph node, quadrisectioned.

B. Additionally labeled #2 and contains a 23.9 gram, 4.5 x 4.0 x 3.0 cm prostate received with attached bilateral adnexa having overall dimensions of 4.0 x 1.8 x 1.0 cm. The capsule is pink-tan and shaggy. The specimen is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with diffuse periurethral nodularity. No discrete masses are identified. Representative sections are submitted in cassettes B1-18 labeled

Source: NCI Genomic Data Commons file 5313b6c7-297a-465e-abb8-d31b6a6d5858 (TCGA-HC-8258.FFFD3795-6C0C-43A0-AFE4-30E759E5F20A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).